Somatic mutation profile of tumor specimen MMRF_1320_1_BM_CD138pos (aliquot MMRF_1320_1_BM_CD138pos_T1_KAS5U_L01371) from MMRF case MMRF_1320, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,123 days).
Specimen MMRF_1320_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 745a2e75-6cc9-40ed-a1e1-9f9eedd70009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1320_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1320_1_PB_Whole_C2_KAS5U_L01383; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d41da748-7304-43f9-8034-c3b4be7de998

The open-access MAF lists 170 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, 3'UTR 42, Intron 18, Silent 15, 5'Flank 13, 5'UTR 6, 3'Flank 4, Splice Site 3, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 53/215 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AK8 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049750; called by muse, mutect2, varscan2
- CEACAM5 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550022667; called by muse, mutect2, varscan2
- CELA3A | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.74); PolyPhen probably damaging (1); catalogued as rs533686702, COSV51583198; called by muse, mutect2, varscan2
- COL24A1 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs772661935; called by muse, mutect2, varscan2
- CSMD1 | c.8221C>T p.H2741Y (on ENST00000520002; = p.H2740Y on NM_033225.6) | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59345572; called by muse, mutect2, varscan2
- DNAH9 | c.4499A>G p.K1500R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as rs1567721166; called by muse, mutect2, varscan2
- EIF4A1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as rs139517056, COSV53442777; called by muse, mutect2, varscan2
- EPHA2 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 122/225 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1248077614, COSV64452132; called by muse, mutect2, varscan2
- FANCI | c.3007-1G>A p.X1003_splice (on ENST00000310775 / NM_001376911.1; = p.X943_splice on NM_018193.3) | Splice Site (SNP) | VAF 24/69 reads (35%) | catalogued as rs117921863; called by muse, mutect2, varscan2
- FNDC1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs776284374, COSV51939875; called by muse, mutect2, varscan2
- H2BC12 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 84/245 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV63616710; called by muse, mutect2, varscan2
- H3C12 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as COSV58152118; called by muse, mutect2, varscan2
- H3C8 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV59952566, COSV59953975; called by muse, mutect2, varscan2
- IGHV2-70 | c.214A>C p.I72L | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs374012300; called by muse, varscan2
- IGKV1-33 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs749512491; called by muse, mutect2
- IGKV2-24 | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 102/106 reads (96%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs769872638; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 42/100 reads (42%) | catalogued as rs181922188; called by muse, varscan2
- IGLV3-1 | c.259A>C p.N87H | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs374619711; called by muse, varscan2
- ITIH2 | c.741G>A p.A247= | Splice Region (SNP) | VAF 39/75 reads (52%) | catalogued as rs769730496, COSV64432783, COSV64434540; called by muse, mutect2, varscan2
- KSR1 | c.1204C>T p.R402W (on ENST00000644974 / NM_001367810.1; = p.R265W on NM_014238.2) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1304389522, COSV52028766; called by muse, mutect2, varscan2
- LMX1B | c.1181C>A p.S394Y (on ENST00000373474 / NM_001174147.2; = p.S387Y on NM_002316.4) | Missense Mutation (SNP) | VAF 84/419 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100826828; called by muse, mutect2, varscan2
- NOL9 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1233758911, COSV100063294; called by muse, mutect2, varscan2
- OXTR | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as rs774330237; called by muse, mutect2, varscan2
- PEG3 | c.1561G>C p.A521P | Missense Mutation (SNP) | VAF 238/459 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99688891; called by muse, mutect2, varscan2
- PLEKHH2 | c.2245A>G p.I749V | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.401); catalogued as rs1330613378; called by muse, mutect2, varscan2
- PTAFR | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs765639817, COSV59536388, COSV59538007; called by muse, mutect2, varscan2
- RNF150 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as rs377250994, COSV100153964; called by muse, mutect2, varscan2
- SH3RF2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767556307; called by muse, mutect2, varscan2
- SLITRK4 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV100567595; called by muse, mutect2, varscan2
- SRCAP | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52682931; called by muse, mutect2
- TCEA2 | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV58657235; called by muse, mutect2, varscan2
- WDFY4 | c.6743G>A p.R2248K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.157); catalogued as rs1021807283; called by muse, mutect2
- ANKRD18A | c.1105T>G p.F369V | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASAP3 | c.1134C>A p.D378E | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CACNA1B | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALN1 | c.636G>T p.Q212H (on ENST00000329008 / NM_001017440.3; = p.Q254H on NM_031468.4) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CASZ1 | c.3136G>A p.D1046N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP112 | c.1600C>A p.Q534K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CKAP2 | c.1034G>T p.R345I (on ENST00000378037 / NM_001098525.2; = p.R344I on NM_018204.5) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CREG2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CROCC | c.3620A>G p.E1207G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CYP4F12 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- DCP1B | c.1550C>G p.A517G | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DUSP8 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- FAM172A | c.264del p.D89Ifs*13 | Frame Shift Del (DEL) | VAF 124/294 reads (42%) | called by mutect2, pindel, varscan2
- FAM227B | c.645+1G>A p.X215_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- FANCM | c.4648A>T p.T1550S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FEM1A | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAP3K5 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- METTL17 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- NUP160 | c.4001C>A p.A1334D | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- PCDHB12 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB6 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCSK5 | c.4344del p.C1449Afs*43 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- PER1 | c.2881C>A p.L961I | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNB1 | c.5588A>T p.D1863V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RBM45 | c.1354dup p.L452Pfs*7 (on ENST00000616198 / NM_001365579.1; = p.L450Pfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 136/354 reads (38%) | called by mutect2, pindel, varscan2
- RBM46 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFX8 | c.611T>C p.I204T (on ENST00000646446; = p.I133T on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SEMA3E | c.2303T>C p.L768P | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHC2 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- SLC2A13 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLIT2 | c.2295A>T p.Q765H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2
- TBXA2R | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TOP2B | c.3055A>T p.N1019Y (on ENST00000264331 / NM_001330700.2; = p.N1014Y on NM_001068.3) | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TUFT1 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- USH2A | c.6089T>C p.V2030A | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- VPS13B | c.2458A>C p.N820H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- VSIG2 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ADAMTS7 | c.3612C>T p.S1204= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- DIAPH3 | c.1260T>A p.V420= (on ENST00000400324 / NM_001042517.2; = p.V157= on NM_030932.3) | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- DPP10 | c.750A>G p.R250= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV59697095; called by muse, mutect2, varscan2
- FUT10 | c.592C>T p.L198= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- H2AC17 | c.237C>T p.I79= | Silent (SNP) | VAF 72/97 reads (74%) | catalogued as rs375215385; called by muse, mutect2, varscan2
- HS3ST3A1 | c.810G>A p.T270= | Silent (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.231T>C p.P77= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as rs558971531; called by muse, varscan2
- KCNK3 | c.294C>T p.H98= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs143689341; called by muse, mutect2
- PRICKLE3 | c.1371T>C p.P457= | Silent (SNP) | VAF 72/74 reads (97%) | called by muse, mutect2, varscan2
- PRR32 | c.429C>T p.G143= | Silent (SNP) | VAF 33/34 reads (97%) | called by muse, mutect2, varscan2
- TINAGL1 | c.819G>A p.G273= | Silent (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- TTC6 | c.1809A>C p.P603= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- UGT2A2 | c.189T>G p.A63= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- ZNF275 | c.486G>A p.R162= | Silent (SNP) | VAF 39/42 reads (93%) | called by muse, mutect2, varscan2
- ZNF804B | c.2340G>A p.Q780= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- ACTN2 | c.784-99G>A | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, varscan2
- AKT3 | c.*53A>G | 3'UTR (SNP) | VAF 98/454 reads (22%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*2128G>A | 3'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499569 del AGTTA | 5'Flank (DEL) | VAF 40/180 reads (22%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65499977 T>A | 5'Flank (SNP) | VAF 67/197 reads (34%) | called by muse, mutect2, varscan2
- APOBEC3B | c.*187A>T | 3'UTR (SNP) | VAF 109/219 reads (50%) | called by muse, mutect2, varscan2
- ARMC8 | c.-93T>G | 5'UTR (SNP) | VAF 51/157 reads (32%) | called by muse, varscan2
- ARMC8 | c.-14T>C | 5'UTR (SNP) | VAF 60/168 reads (36%) | called by muse, varscan2
- ATXN1L | c.-65G>A | 5'UTR (SNP) | VAF 15/19 reads (79%) | catalogued as rs1358663435; called by muse, mutect2, varscan2
- AZI2 | c.647+427T>A | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- BASP1 | c.*346C>T | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021098 G>T | 5'Flank (SNP) | VAF 48/108 reads (44%) | called by muse, varscan2
- BCL7A | chr12:122021165 A>G | 5'Flank (SNP) | VAF 57/120 reads (48%) | called by muse, varscan2
- BCL7A | chr12:122021291 A>G | 5'Flank (SNP) | VAF 36/86 reads (42%) | called by muse, varscan2
- BCL7A | chr12:122021370 A>T | 5'Flank (SNP) | VAF 56/108 reads (52%) | called by muse, varscan2
- BCL7A | chr12:122021434 G>C | 5'Flank (SNP) | VAF 48/81 reads (59%) | called by muse, varscan2
- BEND4 | c.*6600G>T | 3'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, varscan2
- C8orf74 | c.242-6103G>A | Intron (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- CADM2 | chr3:86066911 T>A | 3'Flank (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- CAP1 | c.*2C>T | 3'UTR (SNP) | VAF 19/88 reads (22%) | catalogued as rs777378618, COSV100472177; called by muse, mutect2, varscan2
- CHM | c.315-7263G>T | Intron (SNP) | VAF 13/14 reads (93%) | catalogued as rs998230708; called by muse, mutect2, varscan2
- CHRM3 | c.*2488T>C | 3'UTR (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- CKMT1A | c.876+135T>A | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, varscan2
- COL6A5 | c.*790C>T | 3'UTR (SNP) | VAF 39/62 reads (63%) | catalogued as rs969487679; called by muse, mutect2, varscan2
- CPNE8 | c.*48T>G | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- CSDC2 | c.-47C>T | 5'UTR (SNP) | VAF 56/110 reads (51%) | catalogued as rs939293411, COSV53448486; called by muse, mutect2
- CYP1B1 | c.*1699C>G | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- DGKI | chr7:137846907 T>C | 5'Flank (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- DUSP2 | c.*103G>A | 3'UTR (SNP) | VAF 30/53 reads (57%) | catalogued as rs1333805095; called by muse, mutect2, varscan2
- EEF1A2 | c.*234C>T | 3'UTR (SNP) | VAF 64/113 reads (57%) | called by muse, mutect2, varscan2
- EIF2S3 | c.*619G>T | 3'UTR (SNP) | VAF 162/165 reads (98%) | called by muse, mutect2, varscan2
- EIF2S3 | c.*620C>A | 3'UTR (SNP) | VAF 161/164 reads (98%) | called by muse, mutect2, varscan2
- ELN | chr7:74068887 C>A | 3'Flank (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2
- EPHA10 | c.850+99G>T | Intron (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- ERGIC2 | c.*2192C>T | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- ETV1 | c.45+254G>A | Intron (SNP) | VAF 204/320 reads (64%) | called by muse, varscan2
- FADS2 | c.619-1477C>A | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- FAM210B | c.*1652A>G | 3'UTR (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- FAT4 | c.*92A>G | 3'UTR (SNP) | VAF 48/250 reads (19%) | catalogued as rs1041154435; called by muse, mutect2, varscan2
- GALNT7 | c.*911G>A | 3'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- GFAP | chr17:44903311 A>G | 3'Flank (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- GUCY1A2 | c.*286C>T | 3'UTR (SNP) | VAF 59/90 reads (66%) | called by muse, mutect2, varscan2
- IGLL5 | c.-83G>A | 5'UTR (SNP) | VAF 30/59 reads (51%) | catalogued as rs559131848, COSV73251118; called by muse, mutect2, varscan2
- KANSL1L | c.1550+101del | Intron (DEL) | VAF 33/76 reads (43%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.*1603G>A | 3'UTR (SNP) | VAF 75/224 reads (33%) | catalogued as rs780560560; called by muse, mutect2, varscan2
- KLF5 | c.*1234G>A | 3'UTR (SNP) | VAF 39/54 reads (72%) | called by muse, mutect2, varscan2
- LINC02551 | n.1037_1038del | RNA (DEL) | VAF 124/270 reads (46%) | called by pindel, varscan2
- LNX1 | c.380+15444G>A | Intron (SNP) | VAF 35/76 reads (46%) | catalogued as rs760271973; called by muse, mutect2, varscan2
- LSM8 | c.32-206G>A | Intron (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- LTB | c.163-128A>G | Intron (SNP) | VAF 102/362 reads (28%) | catalogued as rs947037554; called by muse, varscan2
- MANEA | c.*1590A>C | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2
- MIR5195 | chr14:106851258 C>A | 5'Flank (SNP) | VAF 79/160 reads (49%) | catalogued as rs147455610; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46112215 G>A | 5'Flank (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- MTFP1 | chr22:30425702 G>A | 5'Flank (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- MTOR | c.*415C>T | 3'UTR (SNP) | VAF 136/275 reads (49%) | called by muse, mutect2, varscan2
- NFX1 | c.*243A>G | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- NOVA1 | c.136+724C>A | Intron (SNP) | VAF 84/180 reads (47%) | called by muse, mutect2, varscan2
- NSMF | c.1131+63G>A | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as rs577376729; called by muse, mutect2, varscan2
- ONECUT3 | c.*934G>A | 3'UTR (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- PDE4A | chr19:10416923 C>T | 5'Flank (SNP) | VAF 9/40 reads (23%) | catalogued as rs568897912; called by muse, mutect2, varscan2
- PHAX | c.*1541G>A | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- PHC2 | c.*992A>G | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, varscan2
- PHTF2 | c.1119+918C>T | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- PLRG1 | c.1151+48G>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PREX2 | c.*1639G>A | 3'UTR (SNP) | VAF 45/104 reads (43%) | catalogued as rs890688315; called by muse, mutect2
- PTN | c.*618T>A | 3'UTR (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- RUNX1 | c.-1553A>C | 5'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863458 G>A | 5'Flank (SNP) | VAF 148/308 reads (48%) | called by muse, varscan2
- SERPINB8 | c.721-484C>A | Intron (SNP) | VAF 47/332 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.700C>A | RNA (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- SLC23A2 | c.*3243T>C | 3'UTR (SNP) | VAF 5/91 reads (5%) | catalogued as rs955195984; called by muse, mutect2
- SLITRK5 | c.*472C>A | 3'UTR (SNP) | VAF 47/72 reads (65%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.211+9149T>C | Intron (SNP) | VAF 30/134 reads (22%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.*240G>A | 3'UTR (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- SULF1 | c.*137A>G | 3'UTR (SNP) | VAF 77/152 reads (51%) | called by muse, mutect2, varscan2
- TEAD1 | c.*6734T>A | 3'UTR (SNP) | VAF 7/52 reads (13%) | catalogued as rs1455575619; called by mutect2, varscan2
- TFEC | c.*2607G>T | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- TFEC | c.*2235G>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- TGFB2 | c.*3145dup | 3'UTR (INS) | VAF 16/74 reads (22%) | called by mutect2, varscan2
- TMCC1 | c.*2045T>A | 3'UTR (SNP) | VAF 3/20 reads (15%) | catalogued as rs1251591607, COSV61439651; called by muse, mutect2
- TMPRSS13 | chr11:117902146 T>G | 3'Flank (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- TP53I11 | c.*850C>T | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- TXNL1 | c.*1072A>T | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ZMAT4 | c.*303A>C | 3'UTR (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- ZNF829 | c.*1040C>T | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
